Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6812, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6812-01A (Primary Tumor).

[page 1 of 2]
Case ID		Subject ID	

[page 2 of 2]
Formatted Path Report

LARGE INTESTINE TISSUE CHECKLIST

Specimen type: Excision of tumor

Specimen size: Not specified

Tumor site: Rectus abdominus

Tumor size: 3.5 x 3 x 1 cm

Tumor features: Exophytic (polypoid)

Histologic type: Adenocarcinoma

Histologic grade: Moderately differentiated

Tumor extent: Perirectal tissues

Lymph nodes: 0/1 positive for metastasis
(Regional 0/1)

Margins: Not specified

Evidence of neo-adjuvant treatment: Not
specified

Additional pathologic findings: Not specified

Comments: None

Date of Procurement

Source: NCI Genomic Data Commons file aa0b699a-675f-4a62-8a66-a93d6e7141c4 (TCGA-F5-6812.59B4B08F-A953-4BE2-BEC8-FE9C63C4E8DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).